Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA82, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA82-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

"Bladder + prostate + seminal vesicles":

Per TSS, Squamous differentiation = 30%.

- . Invasive urothelial carcinoma of high-grade with foci of squamous differentiation
- . Size of neoplasm: 4.3 x 2.7 x 1.8 cm
- . Depth of infiltration: up to detrusor muscle
- . Sanguineous vascular invasion: not detected
- . Lymphatic vascular invasion: not detected
- . Perineural invasion: present
- . Prostate, seminal vesicles, vas deferens, right and left ureteral margins and urethral margin: free of tumor

"Right pelvic lymph nodes":

- . 11 lymph nodes were dissected, one of which is compromised by neoplasia (1/11) without capsular transposition

"Left pelvic lymph nodes":

- . 8 nodes were dissected, all free of tumor (0/8)

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Invasive urothelial carcinoma of high grade with foci of squamous differentiation	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	High grade urothelial carcinoma with 30% of squamous differentiation	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case reviewed by _____ based on top slide image sent from BCR.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 7662d38d-86f1-494b-9766-227524698c69 (TCGA-4Z-AA82.E5DA265D-FBA6-4EA0-9383-96C365A9679A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).